Somatic mutation profile of tumor specimen TCGA-AG-A016-01A (aliquot TCGA-AG-A016-01A-01W-A00K-09) from TCGA case TCGA-AG-A016, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 55.2 years (20,178 days).
Specimen TCGA-AG-A016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfdbd991-f430-4b1a-8aa6-55df94d00bf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A016-10A (Blood Derived Normal), aliquot TCGA-AG-A016-10A-01W-A00K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53c8d972-acf8-4f3f-a449-647c02a21234

The open-access MAF lists 100 somatic variants for this specimen: 67 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 31, Nonsense Mutation 4, Frame Shift Ins 2, 3'Flank 1, Intron 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 74/191 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 67/75 reads (89%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- APC | c.3814dup p.S1272Ffs*4 | Frame Shift Ins (INS) | VAF 52/141 reads (37%) | catalogued as CI058181; called by pindel, varscan2
- CALD1 | c.218+1G>A p.X73_splice | Splice Site (SNP) | VAF 25/71 reads (35%) | catalogued as COSV62649592; called by muse, mutect2, varscan2
- CALN1 | c.22G>A p.A8T (on ENST00000329008 / NM_001017440.3; = p.A50T on NM_031468.4) | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs767526121, COSV61141568; called by muse, mutect2, varscan2
- CHAC2 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs772317458, COSV99712093; called by muse, mutect2, varscan2
- CHST4 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 77/131 reads (59%) | catalogued as rs144191969, COSV100632830; called by muse, mutect2, varscan2
- CLCA2 | c.2252C>T p.S751L | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV65288860; called by muse, mutect2, varscan2
- COPG2 | c.2497G>A p.G833S | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1554440195; called by muse, mutect2, varscan2
- CPB1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs765515836, COSV51576407; called by muse, mutect2, varscan2
- CWH43 | c.2034C>A p.Y678* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as COSV56940354; called by muse, mutect2, varscan2
- DNAH2 | c.8377C>T p.R2793W | Missense Mutation (SNP) | VAF 64/73 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138592684; called by muse, mutect2, varscan2
- DNAI1 | c.1454C>T p.T485M | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs137935543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ESRRG | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777160519, COSV100754101; called by muse, mutect2
- FBXL7 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1219818114, COSV61641181; called by muse, mutect2, varscan2
- GPC5 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 139/616 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as rs772838827, COSV65608822; called by muse, mutect2, varscan2
- H2BU1 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs752662647, COSV64209902; called by muse, mutect2, varscan2
- HERC1 | c.8965G>A p.V2989I | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs774657002, COSV71246226; called by muse, mutect2, varscan2
- IRF3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs377410193; called by muse, mutect2, varscan2
- LILRB1 | c.717C>A p.N239K (on ENST00000427581; = p.N203K on NM_006669.6) | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV61119290; called by muse, mutect2
- LRRC36 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1285770485; called by muse, mutect2, varscan2
- MYH4 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs149818821; called by muse, mutect2, varscan2
- MYO5A | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 153/360 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs766669585, COSV62561941; called by muse, mutect2, varscan2
- NR3C2 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); catalogued as rs773405588; called by muse, mutect2, varscan2
- NTNG1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs386352339, COSV53976121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10A2 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 99/271 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.27); catalogued as rs754733341, COSV100224921; called by muse, mutect2, varscan2
- PCDHB16 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV53364840; called by muse, mutect2, varscan2
- PCDHGB7 | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV53926580; called by muse, mutect2, varscan2
- PHKB | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144689991, COSV54517570; called by muse, mutect2, varscan2
- PISD | c.910C>T p.R304W (on ENST00000439502 / NM_001326412.1; = p.R270W on NM_014338.3) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370672474, COSV56717968; called by muse, mutect2, varscan2
- PRMT8 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs768625467; called by muse, mutect2, varscan2
- PYROXD1 | c.820A>G p.I274V | Missense Mutation (SNP) | VAF 147/173 reads (85%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV53710437; called by muse, mutect2, varscan2
- ROCK1 | c.2717G>A p.R906Q | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1380465528, COSV104433354; called by muse, mutect2, varscan2
- RSPO1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs996524953, COSV62974610; called by muse, mutect2, varscan2
- SLC22A6 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs760972754; called by muse, mutect2, varscan2
- SLC6A5 | c.2283C>A p.F761L | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV100117159, COSV54225337; called by muse, mutect2, varscan2
- SMAD4 | c.169T>G p.L57V | Missense Mutation (SNP) | VAF 86/118 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61684595; called by muse, mutect2, varscan2
- TRAPPC2L | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs1272548985, COSV51935603; called by muse, mutect2
- TRIM41 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs772110248, COSV59320083; called by muse, mutect2, varscan2
- TTN | c.34990G>A p.V11664M (on ENST00000591111; = p.V10737M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | PolyPhen benign (0.222); catalogued as rs780550944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.12389C>T p.S4130L (on ENST00000591111; = p.S4084L on NM_003319.4) | Missense Mutation (SNP) | VAF 133/327 reads (41%) | catalogued as rs777547090, COSV60033164; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- UNC13C | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV52891333; called by muse, mutect2, varscan2
- ZBTB46 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.835); catalogued as rs1417079872, COSV55511644; called by muse, varscan2
- ZNF211 | c.1595C>T p.T532M (on ENST00000347302 / NM_198855.4; = p.T545M on NM_006385.5) | Missense Mutation (SNP) | VAF 163/573 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs149154202; called by muse, mutect2, varscan2
- ZNF420 | c.1448C>A p.S483Y | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58495152; called by muse, mutect2, varscan2
- ADGRV1 | c.3068C>A p.T1023K | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CDH8 | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP250 | c.3562G>T p.A1188S | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DTYMK | c.259T>A p.L87M | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FAM98C | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FRYL | c.3359C>T p.P1120L | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HEXB | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- HIVEP3 | c.5426A>T p.K1809M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- KLHL9 | c.1390A>T p.M464L | Missense Mutation (SNP) | VAF 22/467 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- LIG4 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- LRP8 | c.1628G>C p.R543P | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPY | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR6N2 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 162/402 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLS3 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 95/114 reads (83%) | SIFT tolerated (0.24); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PWWP3B | c.1561G>T p.D521Y | Missense Mutation (SNP) | VAF 59/72 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SECISBP2L | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SLC40A1 | c.552_555dup p.I186Qfs*56 | Frame Shift Ins (INS) | VAF 20/96 reads (21%) | called by mutect2, varscan2
- SORCS3 | c.3518A>C p.Q1173P | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPIN3 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 182/225 reads (81%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- THBS1 | c.2759_2767del p.D920_D922del | In Frame Del (DEL) | VAF 25/55 reads (45%) | called by mutect2, pindel, varscan2
- TTLL6 | c.2220G>A p.M740I (on ENST00000393382 / NM_001130918.3; = p.M433I on NM_173623.3) | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF563 | c.1147C>A p.H383N | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADA2 | c.1227C>T p.P409= (on ENST00000262607; = p.P168= on NM_177405.3) | Silent (SNP) | VAF 86/234 reads (37%) | called by muse, mutect2, varscan2
- ADNP2 | c.1482G>A p.P494= | Silent (SNP) | VAF 27/37 reads (73%) | catalogued as rs553494105, COSV51542359; called by muse, mutect2, varscan2
- AGPAT3 | c.723G>A p.L241= | Silent (SNP) | VAF 76/93 reads (82%) | catalogued as COSV52371538; called by muse, mutect2, varscan2
- ARHGEF28 | c.906A>G p.E302= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV55260907; called by muse, mutect2, varscan2
- CCDC85A | c.888G>A p.P296= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs556270823; called by muse, mutect2, varscan2
- CD1A | c.954G>A p.A318= | Silent (SNP) | VAF 227/567 reads (40%) | catalogued as rs768867270, COSV56861045; called by muse, mutect2, varscan2
- CNGB1 | c.1695C>T p.N565= | Silent (SNP) | VAF 50/90 reads (56%) | catalogued as rs757874189, COSV51902811; called by muse, mutect2, varscan2
- EPHB6 | c.1302C>T p.F434= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs950848585, COSV67420134; called by muse, mutect2, varscan2
- FAM155A | c.567G>A p.A189= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1218583967; called by muse, mutect2, varscan2
- HMGB2 | c.33C>A p.G11= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV56633890; called by muse, mutect2, varscan2
- HSPG2 | c.11199C>T p.P3733= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs150968006; called by muse, mutect2, varscan2
- IDI2 | c.642C>T p.D214= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as rs1454280459, COSV52988395, COSV52988642; called by muse, mutect2, varscan2
- IL6R | c.144G>A p.P48= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as rs1365223291, COSV59817362; called by muse, mutect2, varscan2
- KCNC4 | c.372G>T p.P124= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- LBP | c.27G>A p.P9= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs148521627, COSV54138524; called by muse, mutect2, varscan2
- MBNL2 | c.492C>T p.V164= | Silent (SNP) | VAF 63/290 reads (22%) | catalogued as rs1356959294, COSV59122644; called by muse, mutect2, varscan2
- MTCL1 | c.3963G>A p.P1321= (on ENST00000306329 / NM_001378206.1; = p.P1002= on NM_015210.4) | Silent (SNP) | VAF 48/64 reads (75%) | catalogued as rs1406752285; called by muse, mutect2, varscan2
- OR56A1 | c.282G>A p.S94= | Silent (SNP) | VAF 117/287 reads (41%) | catalogued as rs368602860, COSV100360548; called by muse, mutect2, varscan2
- PAPPA2 | c.2448C>T p.D816= | Silent (SNP) | VAF 153/330 reads (46%) | catalogued as COSV62780803; called by muse, mutect2, varscan2
- RBFOX2 | c.687G>A p.E229= (on ENST00000438146 / NM_001349995.2; = p.E159= on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 175/410 reads (43%) | called by muse, mutect2, varscan2
- SGSM1 | c.3132C>T p.N1044= (on ENST00000400359 / NM_001039948.4; = p.N983= on NM_133454.3) | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs771938357, COSV68511399; called by muse, mutect2, varscan2
- SPARCL1 | c.1434C>T p.T478= | Silent (SNP) | VAF 221/545 reads (41%) | catalogued as COSV56802742, COSV56804828; called by muse, mutect2, varscan2
- TBCB | c.705G>A p.P235= | Silent (SNP) | VAF 103/175 reads (59%) | catalogued as rs141544940; called by muse, mutect2, varscan2
- TMEM248 | c.84C>T p.S28= | Silent (SNP) | VAF 73/234 reads (31%) | catalogued as rs780848714, COSV58577729; called by muse, mutect2, varscan2
- TRIM24 | c.594A>G p.K198= | Silent (SNP) | VAF 202/340 reads (59%) | called by muse, mutect2, varscan2
- TUBA3C | c.96C>A p.P32= | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as COSV67139556; called by muse, mutect2, varscan2
- USP7 | c.2607G>A p.K869= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as rs1397729569, COSV61215630; called by muse, mutect2, varscan2
- WWC2 | c.3456C>T p.D1152= | Silent (SNP) | VAF 52/163 reads (32%) | catalogued as rs757052313, COSV67859595; called by muse, mutect2, varscan2
- ZNF131 | c.144C>T p.H48= | Silent (SNP) | VAF 38/77 reads (49%) | called by muse, mutect2, varscan2
- ZNF831 | c.4308C>T p.P1436= | Silent (SNP) | VAF 49/428 reads (11%) | catalogued as rs267606025, COSV64041898; called by muse, mutect2, varscan2
- ZSWIM2 | c.1146C>T p.C382= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs1313017723, COSV99719784; called by muse, mutect2, varscan2
- RAB28 | c.574-1283G>T | Intron (SNP) | VAF 76/189 reads (40%) | catalogued as COSV56539733, COSV56540420; called by muse, mutect2, varscan2
- SMIM12 | chr1:34855571 G>A | 3'Flank (SNP) | VAF 43/105 reads (41%) | catalogued as rs755567962; called by muse, mutect2, varscan2
